Somatic mutation profile of tumor specimen MMRF_2344_1_BM_CD138pos (aliquot MMRF_2344_1_BM_CD138pos_T1_KHS5U_K15221) from MMRF case MMRF_2344, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,384 days).
Specimen MMRF_2344_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80396b6e-7f40-40b6-b7fe-5394b043bd4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2344_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2344_1_PB_Whole_C2_KHS5U_K15208; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87a78c36-3b2b-4b17-886e-ef7aac77c595

The open-access MAF lists 96 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Intron 16, Silent 16, 3'UTR 8, Frame Shift Del 4, 5'UTR 3, RNA 3, Splice Site 3, Nonsense Mutation 3, 5'Flank 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2CD4C | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs1297295735; called by muse, mutect2
- CAP2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs759083931, COSV57734949; called by muse, mutect2, varscan2
- H1-4 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs777376445, COSV56801032; called by muse, mutect2, varscan2
- IGHJ4 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 38/40 reads (95%) | PolyPhen possibly damaging (0.54); catalogued as rs183645858; called by muse, varscan2
- IGHV1-69D | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV3-53 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 179/631 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); catalogued as rs782244844; called by muse, mutect2, varscan2
- IGLV3-1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 89/175 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs373605544; called by muse, varscan2
- KCNJ12 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs143946927, COSV59164722; called by muse, mutect2, varscan2
- KIF19 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs534125965; called by muse, mutect2, varscan2
- KLHL4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 101/103 reads (98%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1400885102; called by muse, mutect2, varscan2
- PCM1 | c.436A>T p.M146L | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as COSV61515147; called by muse, mutect2, varscan2
- PKD2 | c.2596A>G p.K866E | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1480227336; called by muse, mutect2, varscan2
- PNPLA8 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.983); catalogued as rs201353226; called by muse, mutect2
- PPEF2 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs763143738, COSV54423837; called by muse, mutect2, varscan2
- PRR14L | c.4964G>A p.R1655K | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs758451724, COSV57884230; called by muse, mutect2
- PTPRT | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 86/285 reads (30%) | catalogued as COSV61977510; called by muse, mutect2, varscan2
- SALL3 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs1384399552; called by muse, mutect2, varscan2
- SPRR1A | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 130/500 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs151244576, COSV61081100; called by muse, mutect2, varscan2
- TOP2B | c.19T>C p.C7R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1235525179; called by muse, varscan2
- ZFHX4 | c.4294C>T p.R1432C | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761737101, COSV50854696; called by muse, mutect2, varscan2
- ZGRF1 | c.5585G>A p.R1862Q | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1472187828; called by muse, mutect2, varscan2
- ACD | c.832T>C p.C278R (on ENST00000620338; = p.C189R on NM_022914.3) | Missense Mutation (SNP) | VAF 68/72 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRE2 | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- BST2 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC141 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CUL5 | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYLD | c.1125G>A p.W375* | Nonsense Mutation (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- DSCAML1 | c.1118-1G>A p.X373_splice (on ENST00000321322; = p.X313_splice on NM_020693.4) | Splice Site (SNP) | VAF 67/139 reads (48%) | called by muse, mutect2, varscan2
- GPR149 | c.1413_1415del p.N471del | In Frame Del (DEL) | VAF 59/143 reads (41%) | called by pindel, varscan2
- HEPACAM | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ID4 | c.396_414del p.A133Rfs*13 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- IGHV2-70 | c.152_157delinsATAATT p.S51_M53delinsNNL | Missense Mutation (ONP) | VAF 27/28 reads (96%) | called by pindel, varscan2*
- IGHV2-70D | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 45/121 reads (37%) | called by muse, varscan2
- IRAK2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LCT | c.4473_4474del p.Y1492Pfs*17 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- LMTK2 | c.4072T>A p.F1358I | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRBA | c.1301del p.S434Yfs*22 | Frame Shift Del (DEL) | VAF 73/160 reads (46%) | called by mutect2, pindel, varscan2
- MMP27 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MON2 | c.62del p.L21Cfs*23 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | called by mutect2, pindel, varscan2
- NLRP5 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 268/402 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RABEPK | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TMC1 | c.362+2T>A p.X121_splice | Splice Site (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- TXNL1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.404); called by muse, mutect2
- ZBED5 | c.1688A>T p.Y563F | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF430 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 51/193 reads (26%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 73/246 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD61 | c.462G>A p.A154= | Silent (SNP) | VAF 20/238 reads (8%) | catalogued as rs1005269429; called by muse, mutect2
- ASCC3 | c.147G>A p.K49= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100225273, COSV61226211; called by muse, mutect2, varscan2
- ATP6V1C2 | c.87C>T p.S29= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as COSV55359371; called by muse, mutect2, varscan2
- DSE | c.540G>A p.V180= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100528237; called by muse, mutect2, varscan2
- FHDC1 | c.3177C>A p.G1059= | Silent (SNP) | VAF 79/169 reads (47%) | called by muse, mutect2, varscan2
- LYL1 | c.330C>T p.L110= | Silent (SNP) | VAF 35/58 reads (60%) | called by muse, mutect2, varscan2
- NHS | c.336G>A p.A112= | Silent (SNP) | VAF 17/18 reads (94%) | called by muse, mutect2, varscan2
- NYAP2 | c.1251G>A p.P417= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as rs371641080, COSV56012996; called by muse, mutect2, varscan2
- RASL11B | c.72C>T p.C24= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs1317861888; called by muse, mutect2, varscan2
- SLC19A1 | c.996G>A p.A332= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs757260467, COSV100229137; called by muse, mutect2, varscan2
- SLC7A9 | c.1167G>A p.T389= | Silent (SNP) | VAF 60/205 reads (29%) | catalogued as rs368549032, COSV99195201; called by muse, mutect2, varscan2
- TAAR5 | c.267C>T p.P89= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs780841254; called by muse, mutect2, varscan2
- TNXB | c.894C>T p.N298= | Silent (SNP) | VAF 82/170 reads (48%) | called by muse, mutect2, varscan2
- WDR26 | c.48C>T p.S16= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1017677401; called by muse, mutect2, varscan2
- XKR7 | c.867C>T p.D289= | Silent (SNP) | VAF 84/140 reads (60%) | catalogued as rs1303010032, COSV73813317; called by muse, mutect2, varscan2
- ZNF205 | c.1653C>T p.P551= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs904817224; called by muse, mutect2, varscan2
- AC110373.1 | n.448C>T | RNA (SNP) | VAF 12/102 reads (12%) | catalogued as rs1417516665; called by muse, mutect2, varscan2
- ARRB1 | c.1022+139C>A | Intron (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2
- CAMK1D | c.300-35595T>A | Intron (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- CDV3 | c.*859C>T | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- CELF2 | c.1076-2192G>A | Intron (SNP) | VAF 83/166 reads (50%) | catalogued as rs770830439; called by muse, mutect2, varscan2
- CLEC16A | c.2641+212T>C | Intron (SNP) | VAF 102/231 reads (44%) | called by muse, mutect2, varscan2
- CNGA2 | c.*263A>G | 3'UTR (SNP) | VAF 43/45 reads (96%) | called by muse, mutect2, varscan2
- CRCP | c.*789G>T | 3'UTR (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- DNAJC14 | chr12:55832172 T>G | 5'Flank (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- DOCK7 | c.1801-1195G>A | Intron (SNP) | VAF 65/130 reads (50%) | called by muse, mutect2, varscan2
- ETNK1 | c.416+397T>A | Intron (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- GVINP1 | n.2996C>A | RNA (SNP) | VAF 104/219 reads (47%) | called by muse, mutect2, varscan2
- HSPA8 | c.1120+76A>G | Intron (SNP) | VAF 162/375 reads (43%) | catalogued as rs1181548858; called by muse, mutect2, varscan2
- HTT | c.*2117A>C | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- IFT122 | c.-40G>T | 5'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- IFT122 | c.-39A>T | 5'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- IRF5 | c.*754G>A | 3'UTR (SNP) | VAF 51/91 reads (56%) | called by muse, mutect2, varscan2
- KRAS | c.112-7078C>A | Intron (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- MMP25 | c.99+9G>T | Intron (SNP) | VAF 21/45 reads (47%) | catalogued as rs1281056323; called by muse, mutect2, varscan2
- NR1I3 | c.-106G>A | 5'UTR (SNP) | VAF 73/335 reads (22%) | catalogued as rs568943207, COSV63468785; called by muse, mutect2, varscan2
- NSD2 | c.2986-76G>A | Intron (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- PDE1C | c.1892-8884del | Intron (DEL) | VAF 38/76 reads (50%) | catalogued as rs879474817; called by mutect2, varscan2
- PPP2CA | c.*121A>T | 3'UTR (SNP) | VAF 41/151 reads (27%) | catalogued as rs1423096456; called by muse, mutect2, varscan2
- PTPRF | c.*307G>A | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82978505 del AAG | 3'Flank (DEL) | VAF 6/32 reads (19%) | catalogued as rs201561979; called by pindel, varscan2
- RHPN2P1 | n.2428C>T | RNA (SNP) | VAF 129/407 reads (32%) | called by muse, mutect2, varscan2
- RNF43 | c.2308+208T>C | Intron (SNP) | VAF 35/68 reads (51%) | catalogued as rs1271568451; called by muse, mutect2, varscan2
- RORA | c.196+51361C>T | Intron (SNP) | VAF 119/200 reads (60%) | catalogued as rs372625965, COSV55045516; called by muse, mutect2, varscan2
- RSPH3 | chr6:158976823 C>T | 3'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as rs201417234; called by muse, varscan2
- TPK1 | c.*31T>C | 3'UTR (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- TRAPPC4 | c.176-80dup | Intron (INS) | VAF 50/126 reads (40%) | called by mutect2, pindel, varscan2
- WHRN | c.1167-295T>C | Intron (SNP) | VAF 31/55 reads (56%) | called by muse, mutect2, varscan2
- XKR8 | chr1:27959638 T>A | 5'Flank (SNP) | VAF 79/176 reads (45%) | called by muse, mutect2, varscan2
- ZNF493 | c.-132+8121G>T | Intron (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
